TCGA case TCGA-HW-7487 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/42251e02-b687-4bf1-a1b6-e3dd978542e4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 39 years; Vital status: Alive.

Diagnoses (3)
1. Oligodendroglioma, NOS (the primary disease): ICD-O-3 morphology code: 9450/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 39.8 years (14,535 days); Year of diagnosis: 2010; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,382 days (3.8 years); Sites of involvement: Brain, Frontal lobe; Supratentorial localization: White Matter.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 27 days; Days to treatment end: 409 days (1.1 years); Number of cycles: 12; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 871 days (2.4 years); Days to treatment end: 930 days (2.5 years); Treatment dose: 60 Gy; Treatment outcome: Progressive Disease; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Days to treatment start: 948 days (2.6 years); Days to treatment end: 1,249 days (3.4 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Procarbazine; Days to treatment start: 960 days (2.6 years); Days to treatment end: 1,236 days (3.4 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vincristine Sulfate; Days to treatment start: 960 days (2.6 years); Days to treatment end: 1,295 days (3.5 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 1,386 days (3.8 years); Days to treatment end: 1,417 days (3.9 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab + Carboplatin; Days to treatment start: 1,570 days (4.3 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Steroid Therapy; Timepoint category: Preoperative.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 42.1 years (15,375 days); Days to diagnosis: 840 days (2.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 43.5 years (15,891 days); Days to diagnosis: 1,356 days (3.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (5 entries)
- Days to follow up: 409 days (1.1 years); Disease response: With Tumor.
- Days to follow up: 605 days (1.7 years); Disease response: With Tumor.
- Day 840 (post initial treatment): Progression or recurrence: Yes.
- Day 1,356 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 1,382 days (3.8 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Seizure.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HW-7487-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.9; Intermediate dimension: 0.9; Shortest dimension: 0.2.
  Slide TCGA-HW-7487-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-HW-7487-01A-01-BS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 30; Percent normal cells: 30; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-HW-7487-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HW-7487-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligodendroglioma; History neoadjuvant treatment: No; History ionizing radiation to head: No; Tumor status: With tumor; Tumor site: Supratentorial, Frontal Lobe; History seizures: Yes; History neoadjuvant steroid treatment: Yes; Idh1 mutation test indicator: No.
- Drug treatment 1: Regimen number: 5/28 - schedule which represents 5 days out of 28 day cycle; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Post-operative.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Treatment best response: Clinical Progressive Disease.
- Drug treatment 3: Pharmaceutical therapy drug name: Vincristine (sulfate); Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.
- Follow-up form 1: New tumor event diagnosis indicator: No; Tumor status: With tumor.
- Follow-up form 2: Lost to follow-up: No; New tumor event diagnosis indicator: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Stable Disease.
- Follow-up form 3: Lost to follow-up: No; New tumor event diagnosis indicator: Yes; Tumor status: With tumor; New tumor event pharmaceutical treatment: Yes; New tumor event radiation treatment: Yes.
- Follow-up form 4: Lost to follow-up: No; New tumor event diagnosis indicator: Yes; Tumor status: With tumor; New tumor event pharmaceutical treatment: Yes; New tumor event radiation treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,382 days; disease-specific survival: no event (censored), 1,382 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 840 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HW-7487-01A-11D-2023-01): tumor purity 0.56, ploidy 3.82, whole-genome doublings 1.
